Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A2JG, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A2JG-06A (Metastatic).

1CB-0-3
Melanoma, NOS 8720/3
Site: lymph node, iliac C77.5
w/ 7/24/11

DIAGNOSIS

Patient ID – Sample ID

HPA Discrepancy		X

(A) LYMPH NODES, RIGHT ILIAC:

MELANOMA, METASTATIC TO AT LEAST FOUR OF TEN LYMPH NODES (2 / 10).
(Two of these tumor deposits may correspond to matted lymph nodes)SEE COMMENT
Largest tumor deposit size: 100 x 80 mm (PER GROSS REPORT).
Location: INTRAPARENCHYMAL
Extracapsular extension: PRESENT

Please see previous specimen with report of positive labeling with a panmelanocytic cocktail.

(B) LYMPH NODE, RIGHT PARACAVAL, EXCISION:

Two lymph node(s), negative for melanoma (0/ 2).

GROSS DESCRIPTION

(A) ILIAC LYMPH NODE, RIGHT, PAN MEL STAINING, STERILE – Multiple portions of pink-tan and yellow fibroadipose tissue, from which multiple possible lymph nodes are dissected (from 0.2 x 0.2 x 0.2 cm up to 10.0 x 8.0 x 5.0 cm). The largest possible lymph node appears grossly replaced by tumor on serial sectioning, as it shows heterogeneous tan-beige and dark-brown cut surfaces. The tumor also appears to extend directly into fibroadipose tissue. Several other possible lymph nodes appear grossly positive for tumor. Tissue is submitted to the tissue bank, and tissue is taken per the TIL protocol. Representative sections are submitted for permanent evaluation in A.

SECTION CODE: A1-A3, representative sections of the largest possible grossly positive lymph node; A4, A5, each one possible grossly positive lymph node, bisected; A6-A13, each one possible lymph node, bisected; A14, one possible lymph node, trisected; A15, A16, one possible lymph node, serially sectioned; A17, A18, one possible lymph node, serially sectioned; A19, one possible lymph node.

(B) RIGHT PARACAVAL NODE – Received are two tan pink lymph nodes measuring 1.0 x 0.8 x 0.6 cm and 2.5 x 1.0 x 0.8 cm. The lymph nodes are submitted entirely.

SECTION CODE: B1, one lymph node, bisected; B2, B3, one lymph node, serially sectioned.

CLINICAL HISTORY

None given.

SNOMED CODES

Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration.
Entire report and diagnosis completed by:

(these tests have not been

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 07e6d718-2ab8-4317-886f-4f6f3a40c77f (TCGA-D3-A2JG.DD325B81-1AC8-43F5-9D0C-5F43CFD39E31.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).